FM case AD17769 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/7f5b1b0d-9409-4f5e-aae6-b02c8b6ba013

Male, 21.8 years: diagnosis not reported by GDC; metastasis biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 35% (pathologist estimate recorded by GDC). Sample type: Metastatic.
